Surgical pathology report (de-identified scan), TCGA case TCGA-D6-6515, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-6515-01A (Primary Tumor).

REPORT!

page 1 / 1

Examination: Histopathological examination

Material: Lesion resection – tumour of the tongue

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: tumour of the tongue

TCGA – D6 – 6515

Examination performed on:

Macroscopic description:

Part of the tongue sized sized 4.2 x 2.6 x 0.4 cm with a tumour sized 3.1 x 1.7 x 0.9 .

Minimum margin: to the base 0.2 cm, to the side 0.5 cm

Histopathological diagnosis:

Carcinoma planoepitheliale (G3) - akeratodes. Planoepithelial carcinoma (G3) without keratosis

Normal tissue margins as per macroscopic description

Source: NCI Genomic Data Commons file 61558d0f-a2c1-497c-8f27-257cee3445f2 (TCGA-D6-6515.5C3AFF2F-BF27-4A4F-8025-268765E2EC5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).